Somatic mutation profile of tumor specimen TCGA-V4-A9F5-01A (aliquot TCGA-V4-A9F5-01A-11D-A39W-08) from TCGA case TCGA-V4-A9F5, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IV; Age at diagnosis: 85.7 years (31,314 days).
Specimen TCGA-V4-A9F5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 133703aa-9851-4aa3-805b-a8446529861a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9F5-10A (Blood Derived Normal), aliquot TCGA-V4-A9F5-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d51bb477-0a8b-43f5-80bc-8e4f16b88341

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGDIA | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as rs587777553, CM137001, COSV53907073; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 24/52 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- C3 | c.1488C>A p.N496K | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs1458826211; called by muse, mutect2, varscan2
- COL9A1 | c.1622G>A p.G541D | Missense Mutation (SNP) | VAF 19/19 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs755767798; called by muse, mutect2, varscan2
- PRAMEF17 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs878949864; called by muse, mutect2, varscan2
- CMYA5 | c.7837A>C p.K2613Q | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- FAT1 | c.8830G>A p.D2944N | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, mutect2
- KTN1 | c.1040A>G p.D347G | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- EXOC5 | c.1860A>G p.Q620= | Silent (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
